TCGA case TCGA-A6-4105 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/95d4f0c4-5997-4ffb-b876-0ddfeee972bb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 79 years; Vital status: Dead; Days to death: 442 days (1.2 years).

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.2; Tissue or organ of origin: Ascending colon; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Age at diagnosis: 79.7 years (29,097 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 19; Lymphatic invasion present: No; Non nodal tumor deposits: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the eyelid (histology not recorded by GDC). Laterality: Left.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 80.7 years (29,461 days); Days to diagnosis: 364 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS.

Follow-up (2 entries)
- Day 364 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 364 days.
- Days to follow up: 442 days (1.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 83.3 kg; Height: 180.3 cm; BMI: 25.6.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A6-4105-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.6; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-A6-4105-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 30.
  Slide TCGA-A6-4105-01A-01-BS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 65; Percent normal cells: 10; Percent necrosis: 10; Percent stromal cells: 20.
  Slide TCGA-A6-4105-01A-02-BS2: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 10; Percent stromal cells: 10.
- Sample TCGA-A6-4105-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A6-4105-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymphovascular invasion indicator: No; Microsatellite instability: No; Loci tested count: 5; Loci abnormal count: 0; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: Yes; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Skin Left lower eyelid; Other malignancy histological type: Squamous Cell Carcinoma in situ.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -1294.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy skin cancer L eyelid. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 442 days; disease-specific survival: no event (censored), 442 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 364 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A6-4105-01A-02D-1770-01): tumor purity 0.55, ploidy 2.86, whole-genome doublings 1.
